Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHK, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAHK-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 4.0 cm; no invasion of rete testis; angio-invasion present; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD 6 3
Seminoma NOS 9061/3
Site: R Testis NOS
C62.9
7/3 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file ce80a69a-0486-4269-9284-a3f3201131c2 (TCGA-2G-AAHK-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).